Somatic mutation profile of tumor specimen ALCH-B27S-TTP1-A (aliquot ALCH-B27S-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B27S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.0 years (21,545 days).
Specimen ALCH-B27S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39119734-e3fc-4225-b7e4-607c568de815.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27S-NB1-A (Blood Derived Normal), aliquot ALCH-B27S-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f8c22ba-bd6b-4f82-a69a-b4d967f381a0

The open-access MAF lists 259 somatic variants for this specimen: 175 protein-altering or splice-affecting, 43 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 43, Intron 19, Nonsense Mutation 12, 3'UTR 7, Splice Site 5, 3'Flank 4, Frame Shift Del 4, 5'UTR 4, 5'Flank 4, RNA 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC2A1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as rs1413339367, CM101703; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 57/434 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AC114490.3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 80/622 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as COSV64120801; called by muse, mutect2, varscan2
- ANKS1A | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 20/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1282967751; called by muse, mutect2
- APOB | c.5731A>C p.T1911P | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV51949847; called by muse, mutect2, varscan2
- ASF1A | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 42/902 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs1480923321; called by muse, mutect2
- BRINP2 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs768723571, COSV64177620; called by muse, mutect2, varscan2
- CCR6 | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1226290290; called by muse, mutect2
- CEP295 | c.7621G>A p.E2541K | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs989118580; called by muse, varscan2
- CFAP61 | c.3451C>A p.L1151M | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV55632981; called by muse, mutect2, varscan2
- CHAF1A | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 47/430 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100011167; called by muse, mutect2, varscan2
- CLHC1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 50/592 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1389978231; called by muse, mutect2
- CNTN5 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 39/579 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as rs200788939; called by muse, mutect2
- DGKB | c.2150T>G p.V717G | Missense Mutation (SNP) | VAF 48/422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761755283; called by muse, varscan2
- DHX29 | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99286969; called by muse, mutect2, varscan2
- DLGAP5 | c.2089C>G p.P697A | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs754933570, COSV55964930; called by muse, mutect2
- DNAH8 | c.6703A>G p.M2235V | Missense Mutation (SNP) | VAF 207/814 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs757714359; called by muse, mutect2, varscan2
- DPYD | c.2630C>A p.P877Q | Missense Mutation (SNP) | VAF 93/649 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV64607013; called by muse, mutect2, varscan2
- EBF2 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs201102910, COSV68776774, COSV68779417; called by muse, mutect2, varscan2
- FAM71B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs778853067, COSV57229667; called by muse, mutect2, varscan2
- FIGNL1 | c.1395C>G p.I465M | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425895204; called by muse, mutect2, varscan2
- FOXI3 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1390571066; called by muse, mutect2
- GLI2 | c.1534G>A p.G512R (on ENST00000361492 / NM_001374353.1; = p.G529R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772643710; called by muse, mutect2
- GPR107 | c.256-1G>C p.X86_splice | Splice Site (SNP) | VAF 31/210 reads (15%) | catalogued as COSV61277119; called by muse, varscan2
- GRIA2 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV52411854; called by muse, mutect2, varscan2
- GUCY2F | c.71A>T p.H24L | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV54301624; called by muse, mutect2
- HOMER2 | c.1034G>A p.R345Q (on ENST00000304231 / NM_199330.3; = p.R334Q on NM_004839.4) | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199827961; called by muse, mutect2, varscan2
- HTATSF1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); catalogued as rs1569355772; called by muse, mutect2
- IGKV1-9 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 118/816 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.027); catalogued as rs761357192; called by muse, mutect2, varscan2
- IMPG1 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV64062368; called by muse, mutect2
- KCNV1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192812890; called by muse, mutect2
- KCNV1 | c.628del p.R210Vfs*20 | Frame Shift Del (DEL) | VAF 55/455 reads (12%) | catalogued as COSV52085727; called by mutect2, pindel, varscan2
- KIAA1217 | c.376C>G p.H126D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.114); catalogued as COSV100908549; called by muse, mutect2
- KRTAP4-5 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV100576752; called by muse, mutect2, varscan2
- LMO7 | c.3187G>A p.E1063K (on ENST00000357063; = p.E744K on NM_005358.5) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV58542246; called by muse, varscan2
- LPO | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV51857488; called by muse, mutect2, varscan2
- LRRC66 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 30/467 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV58632088, COSV58632786; called by muse, mutect2
- MAGEA1 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 56/461 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV63118624; called by muse, mutect2, varscan2
- MECOM | c.743G>T p.G248V (on ENST00000468789 / NM_001105078.4; = p.G436V on NM_004991.4) | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52965277; called by muse, mutect2
- MFSD6L | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100266566; called by muse, mutect2, varscan2
- MYO16 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1291880607, COSV51798056; called by muse, mutect2
- NPAP1 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV61506411; called by muse, mutect2, varscan2
- OLFML3 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766356216; called by muse, mutect2
- OR8K5 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.243); catalogued as COSV100537153; called by muse, mutect2, varscan2
- PLCE1 | c.1750C>T p.L584F | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV53358873, COSV53362667; called by muse, mutect2, varscan2
- PPP2R1A | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs747537922, COSV59042408; called by muse, mutect2
- PRDM9 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 71/630 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV57003865; called by muse, varscan2
- PTEN | c.200T>G p.I67R | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CM981666, COSV64291076, COSV64292219, COSV64299142; called by muse, mutect2, varscan2
- RALGAPB | c.4432G>T p.E1478* | Nonsense Mutation (SNP) | VAF 67/644 reads (10%) | catalogued as COSV99484858; called by muse, mutect2, varscan2
- RARB | c.247C>T p.R83* (on ENST00000383772 / NM_001290216.2; = p.R76* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 51/359 reads (14%) | catalogued as COSV58066006; called by muse, varscan2
- REG1A | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 20/596 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); catalogued as COSV52070929; called by muse, mutect2
- RXYLT1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.172); catalogued as COSV99707082; called by muse, mutect2, varscan2
- SCARA5 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754297792; called by muse, mutect2, varscan2
- SKAP1 | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100412179; called by muse, mutect2, varscan2
- SPIC | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs771393623; called by muse, mutect2, varscan2
- TAF1C | c.1299G>C p.Q433H | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58987478, COSV58988122; called by muse, mutect2
- TBK1 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as CM1513131; called by muse, varscan2
- TNRC6B | c.4358G>A p.G1453D (on ENST00000454349 / NM_001162501.2; = p.G1343D on NM_015088.3) | Missense Mutation (SNP) | VAF 55/482 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99042567; called by muse, mutect2, varscan2
- UNC5C | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs376193832; called by muse, varscan2
- UROC1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.081); catalogued as COSV99331377; called by muse, mutect2
- USP43 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53302172, COSV53308106; called by muse, mutect2, varscan2
- WASHC4 | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as rs771940177; called by muse, mutect2, varscan2
- ZEB1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 59/503 reads (12%) | catalogued as COSV100314079; called by muse, mutect2, varscan2
- ZNF41 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 22/538 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs933692628; called by muse, mutect2
- ZNF606 | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs897324928; called by muse, mutect2, varscan2
- ZNF708 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV63608680; called by muse, mutect2, varscan2
- ACTRT1 | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ADD2 | c.1050C>A p.S350R | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AGTR1 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- ANAPC16 | c.218-1G>A p.X73_splice | Splice Site (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- ANK1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APLNR | c.719T>A p.L240Q | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ARHGAP33 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 66/501 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ARX | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.246); called by muse, mutect2
- ATP2B4 | c.2891T>C p.F964S | Missense Mutation (SNP) | VAF 68/750 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.12160G>A p.D4054N | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, varscan2
- BRIP1 | c.470A>T p.E157V | Missense Mutation (SNP) | VAF 202/637 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C17orf50 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 195/806 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.3390C>A p.H1130Q | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CALB1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDC14C | c.584T>G p.I195S (on ENST00000428251; = p.I88S on NM_152627.3) | Missense Mutation (SNP) | VAF 49/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CGB5 | c.464C>A p.P155Q | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD1L | c.2408C>G p.A803G | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSNK2A2 | c.318G>T p.V106= | Splice Region (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- CYP2A13 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 89/702 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- DCAF8L1 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.179); called by muse, mutect2
- DDI1 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 46/551 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX23 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- DIDO1 | c.3241G>C p.D1081H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH2 | c.7423G>T p.G2475C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAI3 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- EFCAB5 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EGF | c.3208C>G p.P1070A | Missense Mutation (SNP) | VAF 80/480 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, varscan2
- EVC | c.1773G>T p.Q591H | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- FAM47A | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.066); called by muse, mutect2
- FAM47C | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 46/457 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FOXO4 | c.680C>G p.T227S | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- FOXRED1 | c.813G>A p.V271= | Splice Region (SNP) | VAF 58/600 reads (10%) | called by muse, mutect2
- FTO | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 150/1008 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FZD9 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALR1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GLP2R | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 62/300 reads (21%) | called by muse, varscan2
- HCLS1 | c.1325A>T p.E442V | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- HDAC6 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNF4G | c.241G>T p.A81S (on ENST00000354370 / NM_001330561.2; = p.A128S on NM_004133.5) | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, varscan2
- IGKV3-7 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 64/632 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IL1RAPL2 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.112); called by muse, mutect2
- ITPRID1 | c.879T>A p.C293* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- LMO7 | c.1022C>G p.S341* (on ENST00000357063; = p.S356* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- LONRF3 | c.476G>C p.R159P | Missense Mutation (SNP) | VAF 43/1013 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2
- LRRC14B | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2
- LRRC66 | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- MAP3K14 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- MDH1B | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 60/680 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- MOV10L1 | c.2182G>C p.D728H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.268); called by muse, mutect2
- MUC5AC | c.14059G>A p.E4687K | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MYH9 | c.5765+1G>T p.X1922_splice | Splice Site (SNP) | VAF 86/752 reads (11%) | called by muse, mutect2, varscan2
- MYO1F | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 126/756 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MYOM2 | c.1555G>C p.A519P | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NEBL | c.258G>A p.E86= | Splice Region (SNP) | VAF 55/653 reads (8%) | called by muse, mutect2
- NPAS3 | c.2521C>G p.Q841E (on ENST00000356141 / NM_001164749.2; = p.Q809E on NM_022123.3) | Missense Mutation (SNP) | VAF 153/1196 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NUSAP1 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2
- OR11H6 | c.255del p.L87* | Frame Shift Del (DEL) | VAF 22/214 reads (10%) | called by mutect2, pindel, varscan2
- OR4E2 | c.881T>G p.V294G | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- OR8K5 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- OR9K2 | c.568A>C p.T190P (on ENST00000305377; = p.T168P on NM_001005243.1) | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2
- PAQR7 | c.383A>C p.Q128P | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PHF14 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.083); called by muse, mutect2
- PITPNM3 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 18/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHA5 | c.2270A>T p.Q757L | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2
- PLXNB3 | c.5633G>A p.S1878N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PTCH1 | c.1503+2T>A p.X501_splice | Splice Site (SNP) | VAF 62/483 reads (13%) | called by muse, mutect2, varscan2
- RAPSN | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 74/531 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RNASEH2C | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RNF121 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.292); called by muse, mutect2
- RUNDC3B | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 63/690 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- SACS | c.13108C>G p.Q4370E | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SCN11A | c.2950-1G>A p.X984_splice | Splice Site (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- SCN1A | c.2079G>T p.R693S (on ENST00000303395 / NM_001202435.3; = p.R682S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN1A | c.2078G>C p.R693T (on ENST00000303395 / NM_001202435.3; = p.R682T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCPEP1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 217/618 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SDCCAG8 | c.194G>C p.W65S | Missense Mutation (SNP) | VAF 48/770 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- SDCCAG8 | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 52/770 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2
- SLC9A6 | c.1002C>G p.F334L | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SLCO2B1 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SMARCC1 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, varscan2
- SORCS1 | c.1537G>T p.G513W | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK36 | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STK36 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 19/327 reads (6%) | called by muse, mutect2
- SV2A | c.694A>T p.R232W | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TECPR1 | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 98/1142 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TECPR1 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 96/1140 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEK | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 99/709 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TEX13C | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 64/456 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TNNI3K | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- TRAV5 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TRIM55 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 68/720 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TULP1 | c.1300_1301del p.R434Gfs*9 | Frame Shift Del (DEL) | VAF 83/344 reads (24%) | called by pindel, varscan2
- UBR5 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- UCHL5 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- UTF1 | c.971T>G p.F324C | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- VPS13D | c.11793G>C p.M3931I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR90 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 164/965 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XBP1 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- ZAN | c.5873T>C p.V1958A | Missense Mutation (SNP) | VAF 81/757 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZIC3 | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 79/647 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF275 | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF28 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF319 | c.1564G>C p.A522P | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF420 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 42/315 reads (13%) | called by muse, varscan2
- ZNF420 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 30/274 reads (11%) | called by muse, mutect2, varscan2
- ZNF438 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ZNF518A | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZNF536 | c.1450del p.D484Tfs*15 | Frame Shift Del (DEL) | VAF 37/212 reads (17%) | called by mutect2, pindel, varscan2
- ZNF611 | c.875G>T p.C292F | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANO6 | c.609C>T p.F203= | Silent (SNP) | VAF 27/475 reads (6%) | called by muse, mutect2
- BMP10 | c.351G>T p.P117= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as rs372335613, COSV54897300; called by muse, mutect2, varscan2
- CHCHD4 | c.264A>C p.V88= (on ENST00000396914 / NM_001098502.2; = p.V101= on NM_144636.3) | Silent (SNP) | VAF 50/373 reads (13%) | called by muse, mutect2, varscan2
- CHD9 | c.4302A>T p.I1434= | Silent (SNP) | VAF 39/242 reads (16%) | called by muse, mutect2, varscan2
- CHRNB2 | c.792G>A p.E264= | Silent (SNP) | VAF 44/544 reads (8%) | called by muse, mutect2
- COL22A1 | c.2661T>A p.R887= | Silent (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- DPEP2 | c.945C>G p.S315= | Silent (SNP) | VAF 24/277 reads (9%) | called by muse, mutect2
- FAT3 | c.11925C>T p.V3975= | Silent (SNP) | VAF 72/612 reads (12%) | called by muse, mutect2, varscan2
- FBXO4 | c.972A>G p.P324= | Silent (SNP) | VAF 49/412 reads (12%) | catalogued as rs772685831; called by muse, mutect2, varscan2
- GIMAP8 | c.1401G>T p.R467= | Silent (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- GPR139 | c.912C>T p.F304= | Silent (SNP) | VAF 32/500 reads (6%) | called by muse, mutect2
- GPR161 | c.211C>T p.L71= | Silent (SNP) | VAF 47/421 reads (11%) | called by muse, mutect2, varscan2
- GSPT1 | c.201A>C p.P67= (on ENST00000420576 / NM_001130007.2; = p.P205= on NM_002094.4) | Silent (SNP) | VAF 80/459 reads (17%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.1218G>T p.L406= (on ENST00000394468 / NM_001039372.4; = p.L394= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/380 reads (11%) | called by muse, varscan2
- IL2RB | c.939C>T p.F313= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- INO80 | c.1569G>C p.L523= | Silent (SNP) | VAF 50/292 reads (17%) | called by muse, mutect2, varscan2
- KCNAB1 | c.591G>A p.Q197= (on ENST00000490337 / NM_172160.3; = p.Q186= on NM_003471.3) | Silent (SNP) | VAF 118/617 reads (19%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.648G>T p.V216= | Silent (SNP) | VAF 101/755 reads (13%) | called by muse, mutect2, varscan2
- LRP10 | c.831G>A p.E277= | Silent (SNP) | VAF 40/336 reads (12%) | catalogued as COSV62078846; called by muse, mutect2, varscan2
- NRXN3 | c.492G>A p.E164= (on ENST00000557594 / NM_001272020.2; = p.E796= on NM_004796.6) | Silent (SNP) | VAF 164/476 reads (34%) | called by muse, varscan2
- OR1C1 | c.771C>T p.A257= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as rs755711640, COSV101376172, COSV68715809; called by muse, mutect2
- OR1S2 | c.390C>G p.T130= | Silent (SNP) | VAF 59/479 reads (12%) | catalogued as rs1252522073; called by muse, mutect2, varscan2
- OTUD5 | c.618C>G p.A206= | Silent (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- PTPRD | c.2901G>T p.P967= | Silent (SNP) | VAF 57/433 reads (13%) | called by muse, mutect2, varscan2
- PTPRT | c.1548C>T p.I516= | Silent (SNP) | VAF 42/341 reads (12%) | called by muse, varscan2
- QSOX1 | c.111G>T p.S37= | Silent (SNP) | VAF 87/1001 reads (9%) | catalogued as rs1459521056; called by muse, mutect2
- RRBP1 | c.2379G>A p.T793= (on ENST00000377813 / NM_001365613.2; = p.T360= on NM_004587.3) | Silent (SNP) | VAF 79/666 reads (12%) | catalogued as rs761612426; called by muse, mutect2, varscan2
- SCN4A | c.1275C>T p.I425= | Silent (SNP) | VAF 146/384 reads (38%) | called by muse, varscan2
- SERPINB5 | c.999C>T p.S333= | Silent (SNP) | VAF 58/436 reads (13%) | called by muse, mutect2, varscan2
- SH2B1 | c.1860C>A p.V620= | Silent (SNP) | VAF 68/528 reads (13%) | called by muse, varscan2
- SLC25A28 | c.1059C>T p.I353= | Silent (SNP) | VAF 30/157 reads (19%) | called by muse, varscan2
- SPTBN2 | c.4188G>A p.E1396= | Silent (SNP) | VAF 32/650 reads (5%) | called by muse, mutect2
- SYT1 | c.129G>A p.L43= | Silent (SNP) | VAF 47/249 reads (19%) | catalogued as rs1197148512; called by muse, mutect2, varscan2
- TASOR2 | c.5949A>G p.A1983= | Silent (SNP) | VAF 34/394 reads (9%) | called by muse, mutect2
- TKTL1 | c.1566T>C p.S522= | Silent (SNP) | VAF 28/630 reads (4%) | called by muse, mutect2
- UHRF1 | c.1272C>T p.I424= (on ENST00000612630 / NM_001290050.1; = p.I437= on NM_013282.4) | Silent (SNP) | VAF 65/477 reads (14%) | catalogued as rs756022467, COSV53577315; called by muse, mutect2, varscan2
- UNC79 | c.1869T>C p.C623= (on ENST00000393151 / NM_001346218.2; = p.C446= on NM_020818.5) | Silent (SNP) | VAF 61/418 reads (15%) | called by muse, varscan2
- WDR13 | c.186G>C p.L62= | Silent (SNP) | VAF 42/927 reads (5%) | called by muse, mutect2
- WRN | c.2160G>C p.L720= | Silent (SNP) | VAF 58/326 reads (18%) | called by muse, mutect2, varscan2
- XRN1 | c.4926C>G p.V1642= | Silent (SNP) | VAF 20/335 reads (6%) | called by muse, mutect2
- ZIC3 | c.294C>A p.T98= | Silent (SNP) | VAF 79/642 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.2788T>C p.L930= | Silent (SNP) | VAF 58/242 reads (24%) | called by muse, mutect2, varscan2
- ZNF547 | c.906G>A p.G302= | Silent (SNP) | VAF 50/382 reads (13%) | catalogued as rs752995418, COSV56579654; called by muse, varscan2
- AC092818.1 | n.337G>T | RNA (SNP) | VAF 82/627 reads (13%) | called by muse, mutect2, varscan2
- AMPD1 | c.1488-20C>G | Intron (SNP) | VAF 67/420 reads (16%) | called by muse, varscan2
- ASB18 | c.205+4574G>C | Intron (SNP) | VAF 27/416 reads (6%) | called by muse, mutect2
- CCDC60 | c.170+4829C>G | Intron (SNP) | VAF 25/177 reads (14%) | called by muse, varscan2
- CEACAM21 | c.*7C>A | 3'UTR (SNP) | VAF 36/614 reads (6%) | called by muse, mutect2
- CHRND | c.*80T>A | 3'UTR (SNP) | VAF 32/240 reads (13%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811978 T>A | 3'Flank (SNP) | VAF 64/564 reads (11%) | catalogued as rs1261909538; called by muse, mutect2, varscan2
- CSF2RA | c.*135C>T | 3'UTR (SNP) | VAF 28/391 reads (7%) | catalogued as rs373422224, COSV100817357; called by muse, mutect2
- DMAC2 | c.18+12G>C | Intron (SNP) | VAF 25/419 reads (6%) | called by muse, mutect2
- DNAI2 | c.1347+22G>T | Intron (SNP) | VAF 62/387 reads (16%) | called by muse, mutect2, varscan2
- EIPR1 | c.259+19159A>C | Intron (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- ELP5 | c.-44G>A | 5'UTR (SNP) | VAF 129/693 reads (19%) | catalogued as rs375545737; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055683 G>A | 3'Flank (SNP) | VAF 76/580 reads (13%) | catalogued as rs765601243; called by muse, varscan2
- FAM153CP | chr5:178055744 C>T | 3'Flank (SNP) | VAF 88/838 reads (11%) | catalogued as rs796546309; called by muse, varscan2
- GGTLC2 | chr22:22643124 G>T | 5'Flank (SNP) | VAF 70/970 reads (7%) | called by muse, varscan2
- HSDL2 | c.-50C>G | 5'UTR (SNP) | VAF 100/747 reads (13%) | called by muse, varscan2
- KAZALD1 | chr10:101068029 G>T | 3'Flank (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- KCNAB2 | c.119+9688G>C | Intron (SNP) | VAF 51/260 reads (20%) | called by muse, mutect2, varscan2
- KCTD7 | c.-78G>A | 5'UTR (SNP) | VAF 19/510 reads (4%) | called by muse, mutect2
- LINC01517 | n.206C>G | RNA (SNP) | VAF 52/477 reads (11%) | called by muse, mutect2, varscan2
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 8/119 reads (7%) | catalogued as rs1298787056; called by muse, mutect2
- MYH14 | c.*149G>T | 3'UTR (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- NAPEPLD | chr7:103149398 C>T | 5'Flank (SNP) | VAF 30/172 reads (17%) | catalogued as rs1468228926; called by muse, mutect2, varscan2
- NAPEPLD | chr7:103149399 T>A | 5'Flank (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- NCAPH2 | c.109-726G>A | Intron (SNP) | VAF 26/208 reads (13%) | catalogued as rs778465668; called by muse, mutect2, varscan2
- NPEPL1 | chr20:58691064 C>G | 5'Flank (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2
- NTRK1 | c.359+33G>T | Intron (SNP) | VAF 72/450 reads (16%) | called by muse, varscan2
- PEG10 | c.*641C>T | 3'UTR (SNP) | VAF 147/410 reads (36%) | called by muse, mutect2, varscan2
- PEX5L | c.199-355C>A | Intron (SNP) | VAF 50/365 reads (14%) | called by muse, mutect2, varscan2
- POM121L9P | n.1338G>T | RNA (SNP) | VAF 104/751 reads (14%) | catalogued as rs1450850454; called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1997C>T | Intron (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- RNF103 | c.366+2356G>T | Intron (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- SMS | c.-6C>T | 5'UTR (SNP) | VAF 76/985 reads (8%) | catalogued as rs1406759335; called by muse, mutect2
- SPEF2 | c.4448-4011G>A | Intron (SNP) | VAF 67/381 reads (18%) | called by muse, mutect2, varscan2
- TESPA1 | c.*48C>T | 3'UTR (SNP) | VAF 57/334 reads (17%) | called by muse, mutect2, varscan2
- TEX46 | c.166-23C>G | Intron (SNP) | VAF 16/81 reads (20%) | catalogued as rs192609586; called by muse, varscan2
- TLE4 | c.936+278A>T | Intron (SNP) | VAF 46/368 reads (13%) | called by muse, mutect2, varscan2
- TMEM40 | c.472+21G>C | Intron (SNP) | VAF 31/203 reads (15%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.1423-35G>T | Intron (SNP) | VAF 82/723 reads (11%) | called by muse, mutect2, varscan2
- WDR41 | c.411+13G>A | Intron (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2
- ZNF160 | c.16-619C>T | Intron (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
